Somatic mutation profile of tumor specimen TCGA-D5-6529-01A (aliquot TCGA-D5-6529-01A-11D-1771-10) from TCGA case TCGA-D5-6529, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 69.5 years (25,394 days).
Specimen TCGA-D5-6529-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0407a770-af38-41ec-9193-f58326e68252.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D5-6529-10A (Blood Derived Normal), aliquot TCGA-D5-6529-10A-01D-1771-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/74f3593f-f3cb-4aa2-ad13-1d68b340c4d3

The open-access MAF lists 116 somatic variants for this specimen: 83 protein-altering or splice-affecting, 30 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 72, Silent 30, Nonsense Mutation 7, Intron 2, Frame Shift Del 2, Frame Shift Ins 1, Nonstop Mutation 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 107/319 reads (34%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.44); catalogued as rs112445441, CM125166, COSV55497357, COSV55497388, COSV55522580; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 61/360 reads (17%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- AATK | c.3613C>T p.R1205C (on ENST00000326724 / NM_001080395.3; = p.R1102C on NM_004920.2) | Missense Mutation (SNP) | VAF 22/94 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); catalogued as rs572926712, COSV58364022; called by muse, mutect2, varscan2
- ACACB | c.553C>T p.R185C | Missense Mutation (SNP) | VAF 12/93 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.462); catalogued as rs772690862, COSV58130675; called by muse, mutect2, varscan2
- ADAM23 | c.458T>G p.F153C | Missense Mutation (SNP) | VAF 52/336 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52210689; called by muse, mutect2, varscan2
- AHDC1 | c.2815C>T p.R939W | Missense Mutation (SNP) | VAF 24/120 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs563439857, COSV55937495; called by muse, mutect2, varscan2
- ANKRD54 | c.760del p.Q254Nfs*17 | Frame Shift Del (DEL) | VAF 18/117 reads (15%) | catalogued as COSV53235947; called by mutect2, pindel, varscan2
- AQP8 | c.370G>A p.G124R | Missense Mutation (SNP) | VAF 27/120 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs139054676; called by muse, varscan2
- ARMC4 | c.2792C>A p.A931E | Missense Mutation (SNP) | VAF 19/123 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.821); catalogued as COSV59459500; called by muse, mutect2, varscan2
- ATP8B1 | c.1061G>A p.G354D | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV52173787; called by muse, mutect2
- C8orf33 | c.41C>T p.A14V | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.003); catalogued as COSV58895394; called by muse, mutect2, varscan2
- CHSY3 | c.1703G>A p.S568N | Missense Mutation (SNP) | VAF 17/90 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.811); catalogued as COSV59274169; called by muse, mutect2, varscan2
- CNOT11 | c.599C>T p.T200M | Missense Mutation (SNP) | VAF 36/179 reads (20%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.996); catalogued as rs778787740, COSV56819365; called by muse, mutect2, varscan2
- CYB561 | c.343G>T p.A115S | Missense Mutation (SNP) | VAF 18/103 reads (17%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.534); catalogued as COSV62539540; called by muse, mutect2, varscan2
- CYP2S1 | c.1112T>A p.I371K | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.309); catalogued as COSV59505367; called by muse, mutect2, varscan2
- DMXL1 | c.1309G>T p.D437Y | Missense Mutation (SNP) | VAF 19/109 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); catalogued as COSV60707485; called by muse, mutect2, varscan2
- DPYSL4 | c.211G>A p.D71N | Missense Mutation (SNP) | VAF 28/67 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV58306546; called by muse, mutect2, varscan2
- EPS15 | c.1501G>T p.D501Y | Missense Mutation (SNP) | VAF 53/273 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.301); catalogued as COSV65541048; called by muse, mutect2, varscan2
- ETNK1 | c.322C>T p.Q108* | Nonsense Mutation (SNP) | VAF 72/220 reads (33%) | catalogued as COSV56884352; called by muse, mutect2, varscan2
- FBXO2 | c.577C>G p.L193V | Missense Mutation (SNP) | VAF 22/140 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.119); catalogued as COSV99279070; called by muse, mutect2, varscan2
- FHL5 | c.478G>A p.A160T | Missense Mutation (SNP) | VAF 55/162 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as COSV58735930; called by muse, mutect2, varscan2
- FRMD4A | c.369G>C p.K123N | Missense Mutation (SNP) | VAF 8/71 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV52717997; called by muse, mutect2, varscan2
- GFRA1 | c.1114C>T p.R372W | Missense Mutation (SNP) | VAF 20/75 reads (27%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.936); catalogued as rs147029195; called by muse, mutect2, varscan2
- GRIN3A | c.1165G>A p.V389I | Missense Mutation (SNP) | VAF 32/178 reads (18%) | SIFT tolerated (0.7); PolyPhen benign (0.036); catalogued as rs200120504, CM1414149, COSV62451929; called by muse, mutect2, varscan2
- GRM1 | c.2395C>A p.L799I | Missense Mutation (SNP) | VAF 65/198 reads (33%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.998); catalogued as COSV51118731; called by muse, mutect2, varscan2
- HMCN1 | c.16784G>A p.R5595Q | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.205); catalogued as rs765183136, COSV54908572; called by muse, mutect2, varscan2
- KCNA5 | c.341C>T p.T114M | Missense Mutation (SNP) | VAF 21/135 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV52904544; called by muse, mutect2, varscan2
- KCNQ5 | c.1895G>A p.R632Q | Missense Mutation (SNP) | VAF 12/104 reads (12%) | SIFT tolerated (0.3); PolyPhen benign (0.063); catalogued as rs201200702; called by mutect2, varscan2
- KMT2A | c.10067C>T p.A3356V | Missense Mutation (SNP) | VAF 32/132 reads (24%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.023); catalogued as rs149340870, COSV63283642; called by muse, mutect2, varscan2
- KRT71 | c.877C>T p.R293W | Missense Mutation (SNP) | VAF 67/447 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs763192846, COSV57289454; called by muse, mutect2, varscan2
- KRT83 | c.205G>A p.G69S | Missense Mutation (SNP) | VAF 58/159 reads (36%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as rs776341669, COSV53338170; called by muse, mutect2, varscan2
- LDHAL6B | c.190G>A p.E64K | Missense Mutation (SNP) | VAF 28/98 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.034); catalogued as rs1405922785, COSV55684021; called by muse, mutect2, varscan2
- LRP2 | c.6283C>T p.R2095* | Nonsense Mutation (SNP) | VAF 14/82 reads (17%) | catalogued as rs753549113, COSV55544116; called by muse, mutect2, varscan2
- LRRTM2 | c.1334G>A p.R445K | Missense Mutation (SNP) | VAF 44/250 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.437); catalogued as COSV51220275; called by muse, mutect2, varscan2
- LRRTM4 | c.542G>A p.R181Q | Missense Mutation (SNP) | VAF 20/149 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1271861750, COSV69139383; called by muse, mutect2, varscan2
- MAGEA12 | c.559G>A p.D187N | Missense Mutation (SNP) | VAF 64/223 reads (29%) | SIFT tolerated (0.18); PolyPhen benign (0.411); catalogued as rs1556833511, COSV63294502; called by muse, mutect2, varscan2
- MAP3K19 | c.951C>G p.N317K | Missense Mutation (SNP) | VAF 29/216 reads (13%) | SIFT tolerated (0.36); PolyPhen benign (0.015); catalogued as COSV59637445; called by muse, mutect2, varscan2
- MARF1 | c.2545G>A p.A849T | Missense Mutation (SNP) | VAF 95/451 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV60021047; called by muse, mutect2, varscan2
- MED12L | c.2924A>G p.D975G | Missense Mutation (SNP) | VAF 23/110 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.828); catalogued as COSV99854451; called by muse, mutect2, varscan2
- MYBPC2 | c.962C>T p.A321V | Missense Mutation (SNP) | VAF 34/126 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.889); catalogued as rs751962561, COSV63094068; called by muse, mutect2, varscan2
- NCOA1 | c.92C>T p.T31M | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.715); catalogued as rs769307134, COSV99946957; called by mutect2, varscan2
- NEB | c.15266T>C p.I5089T | Missense Mutation (SNP) | VAF 15/91 reads (16%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.543); catalogued as COSV50875243; called by muse, mutect2, varscan2
- NHS | c.3829G>A p.E1277K | Missense Mutation (SNP) | VAF 56/96 reads (58%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0); catalogued as rs765167409, COSV66272873; called by muse, mutect2, varscan2
- NID1 | c.2704G>A p.D902N | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT tolerated (0.46); PolyPhen benign (0.053); catalogued as COSV99938227; called by muse, mutect2, varscan2
- NLRP7 | c.1780del p.I594Ffs*5 | Frame Shift Del (DEL) | VAF 27/123 reads (22%) | catalogued as COSV60183051; called by mutect2, pindel, varscan2
- NPTX2 | c.794G>A p.G265D | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55716613; called by muse, mutect2, varscan2
- NRAP | c.4690G>A p.G1564R (on ENST00000359988 / NM_001322945.2; = p.G1529R on NM_006175.4) | Missense Mutation (SNP) | VAF 26/178 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.334); catalogued as rs537826540, COSV63489287; called by muse, mutect2, varscan2
- OR1D2 | c.161G>A p.R54H | Missense Mutation (SNP) | VAF 85/278 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs139391156; called by muse, mutect2, varscan2
- OR51F2 | c.277G>T p.E93* | Nonsense Mutation (SNP) | VAF 26/139 reads (19%) | catalogued as COSV59064125; called by muse, mutect2, varscan2
- OR51Q1 | c.890A>G p.K297R | Missense Mutation (SNP) | VAF 18/92 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.235); catalogued as COSV56178226; called by muse, mutect2, varscan2
- OTUD7B | c.1474C>T p.R492W | Missense Mutation (SNP) | VAF 41/299 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as rs1181282676, COSV64915606; called by muse, mutect2, varscan2
- PAX3 | c.829C>T p.Q277* | Nonsense Mutation (SNP) | VAF 20/95 reads (21%) | catalogued as COSV60587026; called by muse, mutect2, varscan2
- PCBP1 | c.299T>A p.L100Q | Missense Mutation (SNP) | VAF 23/69 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as rs1422143141, COSV57849655, COSV57849905, COSV57849936; called by muse, mutect2, varscan2
- PCDHA4 | c.617C>T p.P206L | Missense Mutation (SNP) | VAF 25/89 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.668); catalogued as COSV63544761; called by muse, mutect2, varscan2
- PCDHA9 | c.1904G>A p.R635H | Missense Mutation (SNP) | VAF 22/103 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.997); catalogued as COSV65324524; called by muse, mutect2, varscan2
- PCDHB9 | c.205G>A p.D69N | Missense Mutation (SNP) | VAF 53/377 reads (14%) | SIFT tolerated, low confidence (0.22); PolyPhen probably damaging (0.987); catalogued as rs782596051; called by muse, mutect2, varscan2
- PDC | c.741A>C p.*247Cext*16 | Nonstop Mutation (SNP) | VAF 25/190 reads (13%) | catalogued as COSV100414876; called by muse, mutect2, varscan2
- PPP1R16A | c.1235A>G p.N412S | Missense Mutation (SNP) | VAF 15/108 reads (14%) | SIFT tolerated (0.24); PolyPhen benign (0.021); catalogued as rs1321174885, COSV99477812; called by muse, mutect2, varscan2
- PRTG | c.637C>T p.R213* | Nonsense Mutation (SNP) | VAF 24/96 reads (25%) | catalogued as rs770502904, COSV66837300; called by muse, mutect2, varscan2
- RADX | c.842C>T p.A281V | Missense Mutation (SNP) | VAF 62/283 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.124); catalogued as COSV65318138; called by muse, mutect2, varscan2
- RXRG | c.1294A>G p.K432E | Missense Mutation (SNP) | VAF 14/96 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV63231664; called by muse, mutect2, varscan2
- SEC14L3 | c.1064G>T p.C355F | Missense Mutation (SNP) | VAF 25/111 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); catalogued as COSV53178563; called by muse, mutect2, varscan2
- SIX4 | c.1295C>G p.T432S | Missense Mutation (SNP) | VAF 30/229 reads (13%) | SIFT tolerated (0.26); PolyPhen benign (0.006); catalogued as COSV53668968; called by muse, mutect2, varscan2
- SLC45A2 | c.1418G>T p.G473V | Missense Mutation (SNP) | VAF 37/112 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM067466, COSV56870701, COSV56870863; called by muse, mutect2, varscan2
- SLC6A19 | c.1315G>A p.V439I | Missense Mutation (SNP) | VAF 66/238 reads (28%) | SIFT tolerated (0.43); PolyPhen benign (0.127); catalogued as rs559766213, COSV58670324; called by muse, mutect2, varscan2
- STK25 | c.1195G>A p.G399S | Missense Mutation (SNP) | VAF 23/128 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs1416110172, COSV50869915; called by muse, mutect2, varscan2
- TCHH | c.5777G>A p.R1926H | Missense Mutation (SNP) | VAF 41/239 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.974); catalogued as rs201507732, COSV100915395; called by muse, mutect2, varscan2
- THADA | c.3862C>G p.R1288G | Missense Mutation (SNP) | VAF 21/81 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV57679160; called by muse, mutect2, varscan2
- TM9SF4 | c.1300T>C p.F434L | Missense Mutation (SNP) | VAF 41/194 reads (21%) | SIFT tolerated (0.78); PolyPhen benign (0.323); catalogued as COSV54105434; called by muse, mutect2, varscan2
- TMEM132E | c.949C>T p.R317W (on ENST00000321639; = p.R407W on NM_001304438.2) | Missense Mutation (SNP) | VAF 31/168 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs371393529, COSV58695340; called by muse, mutect2, varscan2
- TMEM38A | c.802G>A p.G268S | Missense Mutation (SNP) | VAF 15/82 reads (18%) | SIFT tolerated (0.94); PolyPhen benign (0.029); catalogued as rs577226448, COSV51818504; called by muse, mutect2, varscan2
- TPO | c.2746C>A p.Q916K | Missense Mutation (SNP) | VAF 20/145 reads (14%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0); catalogued as COSV61097702; called by muse, mutect2, varscan2
- WIZ | c.112G>A p.E38K | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs1172974305, COSV54605721; called by muse, mutect2, varscan2
- ZEB2 | c.1122G>T p.E374D | Missense Mutation (SNP) | VAF 14/182 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0.443); catalogued as COSV100354892; called by muse, mutect2
- ZNF333 | c.1078C>T p.R360C | Missense Mutation (SNP) | VAF 17/114 reads (15%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs748154333, COSV52885263; called by muse, mutect2, varscan2
- ZNF385B | c.156G>C p.E52D | Missense Mutation (SNP) | VAF 24/192 reads (13%) | SIFT tolerated (0.3); PolyPhen benign (0.017); catalogued as COSV69801584; called by muse, mutect2, varscan2
- ZNF407 | c.4639C>T p.R1547* | Nonsense Mutation (SNP) | VAF 10/64 reads (16%) | catalogued as rs1190435598, COSV55247015; called by muse, mutect2, varscan2
- ZNF536 | c.1141C>T p.R381C | Missense Mutation (SNP) | VAF 18/111 reads (16%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as rs905189576, COSV62819778; called by muse, mutect2, varscan2
- ZNF610 | c.1019C>T p.A340V | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.493); catalogued as rs149251185; called by mutect2, varscan2
- ZSWIM8 | c.2432C>T p.P811L | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT tolerated (0.41); PolyPhen benign (0.043); catalogued as rs774259563, COSV67131728; called by muse, mutect2, varscan2
- ERCC6 | c.4459A>T p.K1487* | Nonsense Mutation (SNP) | VAF 8/104 reads (8%) | called by muse, mutect2
- PCDHGB5 | c.191G>A p.R64Q | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.746); called by mutect2, varscan2
- PHC2 | c.1810_1814dup p.F605Lfs*128 (on ENST00000257118 / NM_198040.2; = p.F70Lfs*128 on NM_004427.4) | Frame Shift Ins (INS) | VAF 29/149 reads (19%) | called by mutect2, pindel, varscan2
- ABCA13 | c.9774C>T p.S3258= | Silent (SNP) | VAF 35/218 reads (16%) | catalogued as rs371721140; called by muse, mutect2, varscan2
- ADAMTS2 | c.3327G>A p.P1109= | Silent (SNP) | VAF 43/273 reads (16%) | catalogued as rs769116395, COSV52368942; called by muse, mutect2, varscan2
- ADAMTS2 | c.1593G>C p.G531= | Silent (SNP) | VAF 44/104 reads (42%) | catalogued as rs751599667, COSV51071904, COSV51082417; called by muse, mutect2, varscan2
- CEP63 | c.459G>A p.S153= | Silent (SNP) | VAF 37/156 reads (24%) | catalogued as rs748916221, COSV59675047; called by muse, mutect2, varscan2
- CHAF1B | c.1344C>T p.D448= | Silent (SNP) | VAF 15/62 reads (24%) | catalogued as COSV58439552; called by muse, mutect2, varscan2
- CLEC14A | c.282C>T p.V94= | Silent (SNP) | VAF 6/14 reads (43%) | catalogued as COSV60562077; called by muse, mutect2
- COL4A4 | c.3942T>C p.F1314= | Silent (SNP) | VAF 10/63 reads (16%) | catalogued as COSV61630543; called by muse, mutect2, varscan2
- DMXL1 | c.1308T>C p.S436= | Silent (SNP) | VAF 19/114 reads (17%) | catalogued as COSV60707468; called by muse, mutect2, varscan2
- FOXG1 | c.102C>T p.H34= | Silent (SNP) | VAF 5/26 reads (19%) | catalogued as COSV57398185; called by muse, mutect2, varscan2
- GLT6D1 | c.564C>T p.G188= | Silent (SNP) | VAF 7/49 reads (14%) | catalogued as COSV65627377; called by muse, mutect2, varscan2
- GPR6 | c.924G>A p.A308= | Silent (SNP) | VAF 24/74 reads (32%) | catalogued as rs914230729, COSV51571379; called by muse, mutect2, varscan2
- KIR2DL1 | c.303C>T p.Y101= | Silent (SNP) | VAF 40/66 reads (61%) | catalogued as rs765976891, COSV52408229; called by muse, mutect2, varscan2
- LRP2 | c.8847G>A p.S2949= | Silent (SNP) | VAF 8/47 reads (17%) | catalogued as rs181346149; ClinVar: likely benign; called by muse, mutect2, varscan2
- LRRK2 | c.6001C>T p.L2001= | Silent (SNP) | VAF 23/240 reads (10%) | catalogued as COSV54147735; called by muse, mutect2
- MMP16 | c.210G>A p.Q70= | Silent (SNP) | VAF 23/143 reads (16%) | catalogued as COSV99690151; called by muse, mutect2, varscan2
- NDN | c.804C>T p.R268= | Silent (SNP) | VAF 6/92 reads (7%) | catalogued as COSV59361282; called by muse, mutect2
- NFASC | c.1302G>A p.S434= (on ENST00000339876 / NM_001378329.1; = p.S445= on NM_015090.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 30/107 reads (28%) | catalogued as rs750856686, COSV58361811; called by muse, mutect2, varscan2
- PCDHA11 | c.675C>T p.T225= | Silent (SNP) | VAF 17/83 reads (20%) | catalogued as rs782226363, COSV56485913; called by muse, mutect2, varscan2
- PCDHB8 | c.1611C>T p.R537= | Silent (SNP) | VAF 35/339 reads (10%) | catalogued as rs1233212282, COSV50757947; called by muse, mutect2, varscan2
- PCNP | c.99T>C p.T33= | Silent (SNP) | VAF 30/184 reads (16%) | catalogued as COSV54575308; called by muse, mutect2, varscan2
- POLG | c.1848G>A p.E616= | Silent (SNP) | VAF 11/53 reads (21%) | catalogued as COSV51520306; called by muse, mutect2, varscan2
- PTPRS | c.4164C>T p.N1388= | Silent (SNP) | VAF 32/212 reads (15%) | catalogued as rs140530332; called by muse, mutect2, varscan2
- RAB40A | c.177C>T p.D59= | Silent (SNP) | VAF 65/248 reads (26%) | catalogued as rs1332331893, COSV58490882; called by muse, mutect2, varscan2
- RHO | c.309C>T p.F103= | Silent (SNP) | VAF 19/87 reads (22%) | catalogued as rs149615742; called by muse, mutect2, varscan2
- SCN2A | c.5319G>A p.A1773= | Silent (SNP) | VAF 42/301 reads (14%) | catalogued as rs373913233; ClinVar: conflicting interpretations of pathogenicity / uncertain significance; called by muse, mutect2, varscan2
- SMAD3 | c.147C>T p.D49= | Silent (SNP) | VAF 12/41 reads (29%) | catalogued as rs1464740111, COSV59281936; called by muse, mutect2, varscan2
- TMC3 | c.60C>T p.C20= | Silent (SNP) | VAF 12/56 reads (21%) | catalogued as COSV63922575; called by muse, mutect2, varscan2
- UBR4 | c.4332G>A p.P1444= | Silent (SNP) | VAF 11/67 reads (16%) | catalogued as rs753539355, COSV64385100; called by muse, mutect2, varscan2
- ZNF532 | c.1281G>A p.A427= | Silent (SNP) | VAF 12/63 reads (19%) | catalogued as rs763314246, COSV60172277, COSV60173513; called by muse, mutect2, varscan2
- ZNF536 | c.544C>T p.L182= | Silent (SNP) | VAF 7/43 reads (16%) | catalogued as COSV62820935; called by muse, mutect2, varscan2
- AL590867.2 | n.96C>T | RNA (SNP) | VAF 11/24 reads (46%) | catalogued as rs972701104; called by muse, mutect2, varscan2
- GRIA4 | c.2544+20C>A | Intron (SNP) | VAF 25/104 reads (24%) | catalogued as COSV99234148; called by muse, mutect2, varscan2
- TRIB2 | c.563+1156G>A | Intron (SNP) | VAF 118/870 reads (14%) | catalogued as rs775385892, COSV99331312; called by muse, mutect2, varscan2
